Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5311, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5311-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Headaches, glioma.

TCGA-E1-5311

Gross Examination:

A. "Right temporal brain tumor (Af1)", in formalin. A fragment of yellow-tan to grey-tan tissue measuring 2.1 x 1 x 0.7 cm in greatest dimensions. A portion of the specimen has been previously submitted as frozen section Af1. The frozen section remnant is placed in a mesh bag and submitted in Block A1 and the remaining tissue is sectioned and submitted in toto in Block A2.

B. "Brain tumor (Bf1)", in formalin. Multiple fragments of brain tissue measuring 6 x 5 x 2.5 cm in greatest dimensions. A portion of the specimen has been previously submitted as frozen section Bf1. Frozen section remnant is submitted in Block B1 and the remaining tissue is sectioned and submitted in Block B2-B13.

C. "Glioma right temple", fresh. Multiple fragments of tan to grey to brown tissue measuring 3.5 x 3 x 1.8 cm in aggregate dimensions. Sectioned and submitted in toto in Block C1-C5.

Frozen Section Diagnosis:

Af1: "Right temporal brain tumor": Glioma

Bf1: "Brain tumor": Malignant glioma

Microscopic Examination:

The specimen is a large cortical and white matter resection specimen which exhibits a primary neoplasm. The neoplastic cells predominantly exhibit a perinuclear halo and dispersed chromatin pattern. The mitotic activity is low. Focally, the tumor exhibits vascular proliferation and necrosis without pseudopalisading. The specimen also reveals an ependymal lined wall along one edge of the tissue.

DIAGNOSIS:

A. "RIGHT TEMPORAL BRAIN TUMOR":

GLIOMA.

B. "BRAIN TUMOR":

ANAPLASTIC OLIGODENDROGLIOMA.

C. "GLIOMA RIGHT TEMPLE":

Continued on next page...

Page: 1

DATE:

Patient:

MRN:

Location:

[page 2 of 2]
DIAGNOSIS:

ANAPLASTIC OLIGODENDROGLIOMA.

Verified by: [REDACTED]
(Electronic Signature)

Date Signed: [REDACTED]

** END OF REPORT **

Page: 2

DATE: [REDACTED]

Patient: [REDACTED]

HX No: [REDACTED]

Location: [REDACTED]

Source: NCI Genomic Data Commons file b17668e8-3c65-4766-9426-bc2060dc6e01 (TCGA-E1-5311.F4D55755-105E-4740-B13E-801C5D3BDE5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).